Somatic mutation profile of tumor specimen TCGA-2G-AAGN-01A (aliquot TCGA-2G-AAGN-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGN, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 41.5 years (15,145 days).
Specimen TCGA-2G-AAGN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6e44f58-da11-46d0-b371-f5e4531e19dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGN-10A (Blood Derived Normal), aliquot TCGA-2G-AAGN-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cae9ad3-dbb4-4587-897e-f12dd5634a5a

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 1, 3'UTR 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OGFOD3 | c.838_840del p.F280del | In Frame Del (DEL) | VAF 12/93 reads (13%) | catalogued as rs761945367; called by pindel, varscan2
- FOLR3 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ANK1 | c.1185C>T p.A395= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.429C>T p.L143= | Silent (SNP) | VAF 51/580 reads (9%) | catalogued as rs1383774012; called by muse, mutect2
- EIF2B2 | c.163+9G>T | Intron (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- WASHC3 | c.*4T>C | 3'UTR (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
